Surgical pathology report (de-identified scan), TCGA case TCGA-DD-AAVU, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Mayo Clinic - Rochester, specimen TCGA-DD-AAVU-01A (Primary Tumor).

ICD.O-3
Carcinoma, hepatocellular NOS
8170/3
Site Liver C22.0
QW 4/22/14

DIAGNOSIS:
Liver, right, hemihepatectomy:

1. Hepatocellular carcinoma, S5
- 1) Post-chemoembolization status: absent
- 2) Size of tumor: 4x3.5x2.5cm
- 3) Gross type: nodular
- 4) Satellite nodule: absent
- 5) Histologic type: trabecular
- 6) Cell type: classic cell group
- 7) Edmondson and Steiner's histologic grade:
- The worst differentiation: 3
- The major differentiation: 2
- 8) Fatty change: absent
- 9) Hemorrhage/peliosis: present (2%)
- 10) Tumor necrosis: absent
- 11) Vascular invasion(microscopic): present
- 12) Capsule formation: partial
- 13) Infiltration of capsule: present
- 14) Septal formation: present
- 15) Involvement of a major branch of the portal vein: absent
- 16) Involvement of a major branch of the hepatic vein: absent
- 17) Bile duct invasion: absent
- 18) Serosal invasion: absent
- 19) Surgical margin: clear (safety margin: 6.5cm)
- 20) Intrahepatic metastasis: absent
- 21) Multicentric occurrence: absent
- 22) Pathologic stage: AJCC (pT2). (pT3)
- 23) Related biopsy: none
- 24) Additional pathologic findings
- Chronic hepatitis: HBV-associated
- with a) minimal lobular activity
- b) minimal porto-periportal activity
- c) septal fibrosis
- Cirrhosis: absent
- Dysplasia: absent
2. Cavernous hemangioma, S6
- with size: 1.5x1.5x1.0cm
3. Bile duct cyst (x2)
- with size: 2.5x2x1.5cm, 1x1x0.8cm

Source: NCI Genomic Data Commons file b41d5c4a-75b2-4336-9039-771d8586b1e8 (TCGA-DD-AAVU.08C1D8EA-E936-45D8-961D-02670FAD82CC.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).